Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7091, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7091-01A (Primary Tumor).

[page 1 of 3]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED], the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (D) COMPOSITE RESECTION ANTERIOR MANDIBLE:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING BONE.
Mandibular margins of resection free of tumor.

Entire report and diagnosis completed by: [REDACTED]

DIAGNOSIS

- (A) LEFT NECK CONTENTS, LEVELS I, II, III:
Fourteen lymph nodes free of tumor (0/14).
Salivary gland with fibrosis and inflammation consistent with radiation effect.
- (B) RIGHT NECK CONTENTS, LEVELS I, II, III:
Eleven lymph nodes free of tumor (0/11).
Salivary gland free of tumor.
- (C) ANTERIOR LABIAL MARGIN:
Squamous mucosa, no tumor present.
- (D) COMPOSITE RESECTION ANTERIOR MANDIBLE, FLOOR OF MASS, VENTRAL TONGUE:
INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED.
Tumor thickness 1.4 cm.
LYMPHOVASCULAR INVASION PRESENT.
Perineural invasion not identified.
Margins of resection free of tumor.
Sections of mandible are pending for decalcification.
- (E) LEFT GINGIVAL LINGUAL SULCUS:
Squamous mucosa, no tumor present.
- (F) LEFT LINGUAL MARGIN:
Squamous mucosa, no tumor present.
- (G) ANTERIOR LINGUAL MARGIN:
Squamous mucosa, no tumor present.
- (H) RIGHT LINGUAL MARGIN:
Squamous mucosa, no tumor present.
- (I) RIGHT GINGIVAL LINGUAL SULCUS:
Squamous mucosa, no tumor present.
- (J) TEETH:
Multiple teeth, gross diagnosis only.

[page 2 of 3]
Entire report and diagnosis completed by: [REDACTED]

GROSS DESCRIPTION

(A) CONTENTS LEFT LEVEL I, II, III NECK - Specimen received in three containers.

LEVEL 1 - A portion of fibromuscular tissue, 5.0 x 4.5 x 1.5 cm. A portion of salivary gland, 2.5 x 1.5 x 1.0 cm, is present. No tumor is identified in the salivary gland tissue. Multiple lymph nodes, 0.2-1.0 cm in greatest dimension, are identified, grossly negative.

SECTION CODE: A1, representative section from salivary gland tissue; A2, one bisected lymph node; A3, one bisected lymph node; A4, three lymph nodes; A5, three lymph nodes; A6, one bisected lymph node.

LEVEL 2: A portion of fibromuscular tissue, 3.0 x 2.0 x 1.2 cm. One possible lymph node, 0.5 cm in greatest dimension, is identified. The remainder of the tissue consists predominantly of fibroadipose tissue and vessels. Negative for tumor.

SECTION CODE: A7, one possible lymph node; A8 and A9, remainder of level 2 in toto.

CONTENTS OF LEFT NECK LEVEL 3: A fragment of fibroadipose tissue, 6.0 x 1.0 x 0.5 cm. Six lymph nodes, 0.3-1.5 cm, are identified. No tumor is identified.

SECTION CODE: A10, one bisected lymph node; A11, one bisected lymph node; A12, one bisected lymph node; A13, multiple lymph nodes. [REDACTED]

(B) CONTENTS RIGHT NECK - Specimen received in three containers.

LEVEL 1: Fibroadipose tissue and salivary gland tissue in toto, 5.7 x 4.0 x 1.7 cm. The salivary gland measure 2.7 x 1.8 x 1.5 cm. Grossly negative for tumor. Five lymph nodes, 0.9 cm up to 1.7 cm in greatest dimension, are identified; all grossly negative for metastasis.

SECTION CODE: B1, representative section from salivary gland; B2, one bisected lymph node; B3, one bisected lymph node; B4, one bisected lymph node; B5, one bisected lymph node; B6, one bisected lymph node.

CONTENTS RIGHT NECK LEVEL 2: A fragment of fibroadipose tissue and muscular tissue, 4.0 x 2.7 x 0.9 cm. Three lymph nodes are identified at this level measuring from 1.2 up to 2.3 cm in greatest dimension. All lymph nodes are grossly negative for metastasis.

SECTION CODE: B7 and B8, largest lymph node, bisected; B9, one bisected lymph node; B10, one bisected lymph node.

CONTENTS RIGHT NECK LEVEL 3: A portion of fibroadipose tissue, 6.0 x 1.0 x 0.6 cm. Three lymph nodes, 0.9 cm-1.5 cm, are identified. All lymph nodes are grossly negative for metastasis.

SECTION CODE: B11, one bisected lymph node; B12, one bisected lymph node; B13, one bisected lymph node. [REDACTED]

(C) ANTERIOR LABIAL MARGIN - A slender mucosal strip (4.7 x 0.3 x 0.3 cm) without any orientation. Entirely frozen for intraoperative consultation in C. [REDACTED]

*FS/DX: BENIGN SQUAMOUS MUCOSA AND SOFT TISSUE, NO TUMOR PRESENT. [REDACTED]

*FS/DX: BENIGN SQUAMOUS MUCOSA AND SOFT TISSUE, NO TUMOR PRESENT. [REDACTED]

[page 3 of 3]
(D) COMPOSITE RESECTION ANTERIOR MANDIBLE, FLOOR OF MOUTH, VENTRAL TONGUE - A composite resection specimen (6.0 x 6.0 x 6.0 cm) consisting of anterior mandible (6.0 x 6.0 x 2.5 cm), floor of mouth and ventral tongue (3.0 x 2.0 x 2.0 cm).

There is an ulcerating, tan-gray, firm tumor involving the medial floor of mouth obliterating the lingual frenulum and eroding anteriorly through the mandible to involve the alveoli of the two first incisors and the left second incisor. The tumor protrudes into the vestibular gingiva and is located within 0.5 cm of the anterior gingival margin and 1.5 cm of the deep soft tissue margin. All resection margins appear grossly uninvolved. The remaining teeth, mandible, tongue, and soft tissues of the floor of mouth are unremarkable without discrete lesions.

SECTION CODE: D1-D12, representative of tumor. The involved dental alveoli are submitted to the bone lab for decalcification and sectioning.

(E) LEFT GINGIVAL LINGUAL SULCUS - A 1.3 cm slender strip of mucosa, entirely frozen in E. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(F) LEFT LINGUAL MARGIN - A 3.2 cm slender strip of mucosa, entirely frozen in F. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(G) ANTERIOR LINGUAL MARGIN - A 2.7 cm slender strip of mucosa, entirely frozen in G. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(H) RIGHT LINGUAL MARGIN - A 2.1 cm slender strip of mucosa, entirely frozen in H. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(I) RIGHT GINGIVAL LINGUAL SULCUS - A 1.3 cm slender strip of mucosa, entirely frozen in I. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(J) TEETH - Multiple teeth and fragments of teeth including incisors, premolars, canines and molars some of which have amalgam. No sections taken, gross documentation only. [REDACTED]

SNOMED CODES

M-80703 T-11180

Source: NCI Genomic Data Commons file d804b953-ca38-44db-8d68-1c75666d76e1 (TCGA-CV-7091.1A77FE57-E3AE-4897-824B-EF8A1B7E5FC8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).